Somatic mutation profile of tumor specimen TCGA-UZ-A9PN-01A (aliquot TCGA-UZ-A9PN-01A-11D-A382-10) from TCGA case TCGA-UZ-A9PN, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III.
Specimen TCGA-UZ-A9PN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 636de9b7-0072-4b31-b210-460a8c56307b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PN-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PN-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/223f94a9-3146-4a5c-a59b-e8a3c825cfe0

The open-access MAF lists 62 somatic variants for this specimen: 47 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Del 4, Intron 2, Translation Start Site 1, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD14A-ACY1 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.547); catalogued as COSV99865293; called by muse, mutect2, varscan2
- ADNP | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV100823653; called by muse, mutect2, varscan2
- AKT2 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100251432; called by muse, mutect2, varscan2
- ANKRD44 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.094); catalogued as rs150303870; called by muse, mutect2, varscan2
- ASCC3 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV100225321; called by muse, mutect2, varscan2
- BRD4 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs200902225, COSV99650010; called by muse, mutect2, varscan2
- CACNA1S | c.3232A>C p.N1078H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100754712; called by muse, mutect2, varscan2
- CNTNAP5 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 66/255 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs200795882; called by muse, mutect2, varscan2
- COL11A1 | c.1870C>G p.P624A | Missense Mutation (SNP) | VAF 105/471 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV100615384; called by muse, mutect2, varscan2
- COL1A2 | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99798765; called by muse, mutect2, varscan2
- DCTPP1 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100073500; called by muse, mutect2, varscan2
- ERBB3 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV99916021; called by muse, mutect2, varscan2
- GIGYF2 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV101004019, COSV101004085; called by muse, mutect2, varscan2
- GLYAT | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV53539564, COSV99557139; called by muse, mutect2, varscan2
- GPR137 | c.1131C>A p.H377Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100463982; called by muse, mutect2
- HIVEP1 | c.7145G>A p.S2382N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101044789; called by muse, mutect2, varscan2
- JAG1 | c.1894G>T p.D632Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99652504; called by muse, mutect2, varscan2
- KRTAP10-8 | c.780A>T p.*260Cext*11 | Nonstop Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100552153; called by muse, mutect2, varscan2
- LAMC2 | c.1631A>G p.N544S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV99917127; called by muse, mutect2, varscan2
- MOCOS | c.1760T>G p.L587R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99732871; called by muse, mutect2
- MRNIP | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs112467347; called by muse, mutect2, varscan2
- NLGN4X | c.1850A>C p.D617A | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV99320187; called by muse, mutect2, varscan2
- NNT | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99238480; called by muse, mutect2, varscan2
- NPR1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.695); catalogued as COSV100903731; called by muse, mutect2, varscan2
- NVL | c.2311G>T p.D771Y | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV99893773; called by muse, mutect2, varscan2
- POTEE | c.1964T>C p.I655T | Missense Mutation (SNP) | VAF 106/449 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100387156; called by muse, mutect2, varscan2
- PRR12 | c.1922C>G p.P641R (on ENST00000615927; = p.P1462R on NM_020719.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.22); catalogued as COSV101330586; called by muse, mutect2, varscan2
- RPL28 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100689352; called by muse, mutect2, varscan2
- SETBP1 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV99952267; called by muse, mutect2, varscan2
- SH3GL3 | c.74A>C p.E25A | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100196040; called by muse, mutect2, varscan2
- SLC25A11 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99337246; called by muse, mutect2, varscan2
- SPIN1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 110/425 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV101020915; called by muse, mutect2, varscan2
- SPON1 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV100115331; called by muse, mutect2, varscan2
- ST18 | c.3055A>G p.M1019V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99388515; called by muse, mutect2, varscan2
- STAB2 | c.1990C>T p.R664* | Nonsense Mutation (SNP) | VAF 47/142 reads (33%) | catalogued as rs768497627, COSV66344169; called by muse, mutect2, varscan2
- TMUB2 | c.706T>A p.C236S (on ENST00000538716 / NM_001353177.2; = p.C216S on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.285); catalogued as COSV100116037; called by muse, mutect2, varscan2
- TMX3 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100218252; called by muse, mutect2, varscan2
- TNRC6C | c.4253C>G p.P1418R | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV100049550; called by muse, mutect2, varscan2
- TWF1 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 100/439 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs753601193, COSV57301385; called by muse, mutect2, varscan2
- UGT1A10 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100761387; called by muse, mutect2, varscan2
- WDR19 | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV99975242; called by muse, mutect2, varscan2
- AGK | c.1255del p.S419Afs*70 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- CAMK2N2 | c.38del p.G13Afs*46 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- RELA | c.1228_1251del p.V410_P417del | In Frame Del (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- SLC46A1 | c.1155_1156del p.E385Dfs*15 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by pindel, varscan2
- SPTBN5 | c.8923dup p.Q2975Pfs*33 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- TOMM40L | c.714_717del p.N238Kfs*14 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | called by mutect2, pindel, varscan2
- DAXX | c.249G>A p.E83= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV99801572; called by muse, mutect2, varscan2
- FHOD3 | c.972C>T p.H324= | Silent (SNP) | VAF 39/157 reads (25%) | catalogued as rs201237691, COSV57188158; called by muse, mutect2, varscan2
- HOXC6 | c.45C>T p.A15= | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as rs757138274, COSV99678948; called by muse, mutect2, varscan2
- INPP5D | c.3153G>A p.P1051= (on ENST00000445964 / NM_001017915.3; = p.P1050= on NM_005541.5) | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as rs773563073, COSV64038344; called by muse, mutect2, varscan2
- IQGAP3 | c.1332C>A p.L444= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV100752086; called by muse, mutect2, varscan2
- LRP1B | c.5019G>A p.T1673= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs373983727; called by muse, mutect2, varscan2
- MFSD12 | c.1395G>A p.L465= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs1171783548, COSV100281279; called by muse, mutect2, varscan2
- OGFR | c.969C>A p.A323= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV99283780; called by muse, mutect2, varscan2
- PCDHB15 | c.1377C>T p.F459= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs782453925, COSV99178826; called by muse, mutect2, varscan2
- PDHX | c.1140T>C p.D380= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99927256; called by muse, mutect2, varscan2
- PPP1R3F | c.2103G>A p.G701= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as rs782392264, COSV99278480; called by muse, mutect2, varscan2
- RHBDL1 | c.858G>A p.L286= (on ENST00000219551 / NM_001318733.2; = p.L221= on NM_001278720.2) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99555440; called by muse, mutect2, varscan2
- ZNF770 | c.240T>C p.P80= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV100695839; called by muse, mutect2, varscan2
- NFATC3 | c.3107-11987A>G | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100284931; called by muse, mutect2, varscan2
- XKR6 | c.765-110450G>C | Intron (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101130992; called by muse, mutect2, varscan2
